Surgical pathology report (de-identified scan), TCGA case TCGA-66-2782, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2782-01A (Primary Tumor).

[page 1 of 3]
Material examined:

Right upper lobe and others

Clinical diagnosis and question

Bronchial carcinoma right upper lobe.

REPORT ON FINDINGS**Macroscopy**

1) Mediastinal biopsy: flat preparation rich in fatty tissue, 1 cm in size, accumulation of blood on the upper surface.

2) Right upper lobe: Inflated, fixed preparation $19 \times 12 \times 8$ cm in size, with predominantly hazy, cloudy, coated pleura with brownish red coated over the apex, moderately to very patchy or reticulate grayish black markings on the surface. Over the lateral and laterodorsal parts of segments 1 + 2 part of the chest wall adhering to the surface measuring up to 10.5×8.5 cm with inclusion of two rib segments, each end smoothly separated. Beneath this a solid tumor, in places with relatively clear arcuate demarcation against the surrounding parenchyma, max. 8.5 cm in diameter, extending from the center to the periphery, taking up at least half the preparation, with dirty, grayish white section surfaces and slate-gray towards the center. On the sawn section surfaces infiltration of the visceral and parietal pleura in an area at least 4 cm in size and continuous spreading into the subpleural fatty tissue, both rib segments intact. Towards the cranial circumferential border of the part of the chest wall, narrow, extended and running tangentially to the pleura, where tumor tissue could hardly be distinguished from the fused and blackish whitish thickened pleural lamina. B1 and 2 not identifiable within the tumor mass, incursion into the lumen also in the central section of B3, also here at least 1 sub-segment branch incorporated into the tumor and destroyed by it there, the others moderately extended towards the periphery and with tough, viscous material in the lumen. Extending from the previous B1/2 bifurcation region, whitish tumor tissue severely constricting the upper lobe ostium and growing into the lumen of the main bronchus from the outside. Bronchus displaced like a cuff, resection lines about 7 mm proximally and 5 mm distally of the upper lobe ostium by the main and the intermediate bronchus, where the central resection border was marked with thread. The visceral pleura was pushed forward in places by the tumor over the medial and lateral mediastinal parts. Pale grayish yellow densities in segments 1 and 2 in particular, but also in segment 3, plus small or very small patches of grayish white induration zones, striated in places, especially in S1. Two solid, pigmented nodes up to 1.8 cm in the peribronchial and hilar fatty tissue, the larger with focal, pale gray section surfaces.

3) Left mediastinal repeat resectate: flat, fibrous, irregular, fatty preparation with surface smooth in places and rather irregular in places, and clip in the vicinity of one end.

4) Hilar LN (item 10) right: part of a pigmented node 2.8 cm in size.

5) Subcarinal LN (item 7): part of a pigmented node 2.6 cm in size with some fatty surrounding tissue and light grayish white section surfaces in places.

6) Hilar LN (item 10) left: longitudinal, fatty in places, grayish black in places, measuring 1.7 cm.

[page 2 of 3]
Examined

1) Rapid section residue + residual material,

2) Central (thread marked) resection line of main bronchus, peripheral bronchus resection line of intermediate bronchus, upper lobe ostium + central tumor, central B3 tumor, 2 tumors with part of chest wall (e: with both rib segments, f: cranial circumferential border; color marking of external and circumferential section surfaces), 3 sections with S1 peripheral tumor parenchyma, displacement borders of the vessels + small nodes (include in b), larger nodes laminated by the bronchial stump (l),

3) Laminated preparation,

4) + 5) Laminated preparation,

6) Total preparation,

15 blocks.

Microscopy

Re. 1) Intra-operative immediate evaluation (): inflammatory infiltration of the pleura (?), some abnormally large cells included, but no evidence of tumor.

Re. 2) Intra-operative immediate evaluation (): both displacement borders free of tumor.

Description of the histological and cytological findings omitted for reasons of capacity.

EVALUATION

Very large and locally advanced large and spindle cell, nonkeratinizing squamous cell carcinoma (WHO category 1.3.1) of the right upper pulmonary lobe, extending from the center to the periphery, with obliterating endobronchial growth in places, histologically poorly differentiated, with primary location in segments 1 and 2 and extension into the soft tissue of the parts of the chest wall with adhesions. Lymphatic or hemangioma tumor propagation at the central border of the bronchial cuff in parabronchial fatty tissue. Mucosa and wall of the central bronchus resection line, peripheral border of the bronchial cuff, vascular displacement borders, removal borders of the thoracic resectate, hilar resection surfaces, the lymph nodes from samples 2) and 4) - 6) and the parts of the parietal pleura in samples 1) and 3), which show fibrinous, active, chronic inflammation in places, are free of tumor. Focal, active, chronic retention pneumonia and already old, sub-pleural zones of necrosis showing distinctive, chronically organizing and yellow brown deposits of pigment of uncertain origin in the vicinity of the tumor (site of previous removal of tissue? small peripheral pulmonary infarction?). Also peripheral, active, chronic bronchitis and bronchiolitis with focal intra-alveolar mucosal retention, the substrate of respiratory bronchiolitis and mild, focal pulmonary emphysema.

[page 3 of 3]
TNM classification pT3 pN0 L1 or V1, stage IIB.

Morphology: 80703

Topography: 028100

Morphology: 8070/3

Topography: C34.1

Grading: 3

Stage: T3N0MXR0

Source: NCI Genomic Data Commons file 65d94578-764a-4c40-ba6b-e91e9111c9d8 (TCGA-66-2782.BDAE0797-B3E2-47FD-B95B-20D4510277B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).